Somatic mutation profile of tumor specimen MP2PRT-PAVMHE-TMP1-A (aliquot MP2PRT-PAVMHE-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVMHE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.1 years (2,223 days).
Specimen MP2PRT-PAVMHE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68759ef7-dc0b-4554-be58-0aafc0ba83cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMHE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMHE-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b4d1a48-c9e5-407c-adb8-6b2b10255bf6

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 150/312 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755437867, COSV57147931; called by muse, mutect2, varscan2
- C8A | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs759882349, COSV63484771; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2
- KRT78 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 39/458 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1565702424, COSV100467206; called by muse, mutect2
- MTUS1 | c.3650C>T p.S1217L (on ENST00000262102 / NM_001363061.1; = p.S383L on NM_020749.4) | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746217713; called by muse, mutect2, varscan2
- PTH1R | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 130/289 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs148778122; called by muse, mutect2, varscan2
- PTPRG | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 58/383 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.306); catalogued as rs759881134, COSV55640897; called by muse, mutect2, varscan2
- RASGRF2 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs747659788, COSV54122180; called by muse, mutect2, varscan2
- SULT6B1 | c.179T>A p.L60Q (on ENST00000535679 / NM_001367551.1; = p.L22Q on NM_001032377.2) | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99573320; called by muse, mutect2, varscan2
- ZNF729 | c.973T>A p.C325S | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1264569929; called by muse, mutect2, varscan2
- FAM83H | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 232/512 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, varscan2
- SF3A1 | c.226A>T p.I76F | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATP1B1 | c.9C>T p.R3= | Silent (SNP) | VAF 93/234 reads (40%) | called by muse, mutect2, varscan2
- INTS5 | c.1428G>A p.A476= | Silent (SNP) | VAF 108/306 reads (35%) | catalogued as rs148424471; called by muse, varscan2
- PCDHB11 | c.618G>A p.P206= | Silent (SNP) | VAF 20/362 reads (6%) | catalogued as rs115271920; called by muse, mutect2
- RBFOX1 | c.300C>T p.G100= | Silent (SNP) | VAF 115/302 reads (38%) | catalogued as rs377433712; called by muse, mutect2, varscan2
- SLC38A10 | c.120G>A p.A40= | Silent (SNP) | VAF 110/266 reads (41%) | catalogued as rs751852614, COSV55849771; called by muse, varscan2
